Somatic mutation profile of tumor specimen TCGA-VS-A9U5-01A (aliquot TCGA-VS-A9U5-01A-11D-A42O-09) from TCGA case TCGA-VS-A9U5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 57.9 years (21,149 days).
Specimen TCGA-VS-A9U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88896cb5-0acf-42a2-8f16-d0e30b44ba89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9U5-10A (Blood Derived Normal), aliquot TCGA-VS-A9U5-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/025370fc-e26b-401b-8c62-ead4a08de236

The open-access MAF lists 86 somatic variants for this specimen: 59 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 25, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAA2 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as COSV99551866; called by muse, mutect2
- ACTN3 | c.1448C>A p.A483E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as COSV100074304; called by muse, mutect2, varscan2
- AL133500.1 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.2); catalogued as COSV99860348; called by muse, mutect2
- ANKRD29 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754976508; called by muse, mutect2, varscan2
- CASP2 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs139233385; called by muse, mutect2, varscan2
- CD44 | c.1790A>C p.N597T | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99555749; called by muse, mutect2
- CHD6 | c.6169A>G p.T2057A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100951067; called by muse, mutect2, varscan2
- CHST7 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99332990; called by muse, mutect2, varscan2
- CNTN2 | c.2509C>A p.Q837K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as COSV100085088; called by muse, mutect2
- COL3A1 | c.2834G>A p.G945D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100483108; called by muse, mutect2, varscan2
- COPS2 | c.738G>C p.L246F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54645022; called by muse, mutect2
- CSMD1 | c.2760G>A p.W920* (on ENST00000520002; = p.W919* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 21/30 reads (70%) | catalogued as COSV100150351, COSV59312360; called by muse, mutect2, varscan2
- CTNND2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV100477268; called by muse, mutect2, varscan2
- DEAF1 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100102063; called by muse, mutect2, varscan2
- DNAH9 | c.6322G>A p.D2108N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.11); catalogued as COSV52332209, COSV99306099; called by mutect2, varscan2
- DOK2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs867150796, COSV99374756; called by muse, mutect2, varscan2
- EFNB2 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1464916257, COSV55363345; called by muse, mutect2, varscan2
- GDF3 | c.676A>G p.R226G | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100325288; called by muse, mutect2, varscan2
- GPR39 | c.1007G>C p.S336T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100257815; called by muse, mutect2, varscan2
- HDX | c.1252-1G>T p.X418_splice | Splice Site (SNP) | VAF 12/119 reads (10%) | catalogued as COSV99947368; called by muse, mutect2
- HLTF | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 9/182 reads (5%) | catalogued as COSV100026870; called by muse, mutect2
- IGSF9B | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV100317762; called by mutect2, varscan2
- IL2RA | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs147791171; called by muse, mutect2, varscan2
- JAKMIP3 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as rs745792121, COSV53824595; called by muse, varscan2
- KIF16B | c.3784A>T p.S1262C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV100734382; called by muse, mutect2, varscan2
- KLHL20 | c.1069G>C p.G357R | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV52941802, COSV99268434; called by muse, mutect2
- MAGEB6 | c.701del p.P234Lfs*19 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as COSV66871960; called by mutect2, pindel, varscan2
- MOAP1 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs774501324, COSV52093604; called by muse, mutect2, varscan2
- MUC16 | c.38950C>T p.P12984S | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as rs750021447, COSV67454379; called by muse, mutect2, varscan2
- MUC16 | c.34751C>A p.T11584N | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV101200036; called by muse, mutect2, varscan2
- MYORG | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52626074, COSV99898644; called by muse, varscan2
- NLRP1 | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as COSV52575575, COSV99334297; called by muse, mutect2, varscan2
- OR2B2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as rs201539002, COSV57579191; called by muse, mutect2, varscan2
- OR5H14 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.495); catalogued as COSV101454198; called by muse, varscan2
- OR5H14 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101454199; called by muse, varscan2
- OTOF | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746386736, COSV55523319; called by muse, mutect2, varscan2
- OTP | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.295); catalogued as COSV100119822; called by muse, mutect2, varscan2
- PCDHB16 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV53361604; called by muse, mutect2, varscan2
- PDZD4 | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782392156, COSV51246001; called by muse, mutect2, varscan2
- PLXNA2 | c.5009G>A p.S1670N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV100885549; called by muse, mutect2
- PODN | c.71C>G p.S24W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV100439621; called by muse, mutect2, varscan2
- PRPF8 | c.4109G>A p.R1370H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100517526; called by muse, mutect2, varscan2
- PSMC5 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV56742324; called by muse, mutect2, varscan2
- PTPRE | c.2028+1G>A p.X676_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99618013; called by muse, mutect2, varscan2
- SENP2 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99957805; called by muse, mutect2
- SGCD | c.194G>A p.G65E (on ENST00000435422 / NM_001128209.2; = p.G66E on NM_000337.5) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550074, COSV100551337; called by muse, mutect2
- SIN3B | c.2393T>A p.I798N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99931760; called by muse, mutect2, varscan2
- SLC38A1 | c.1309C>G p.L437V | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV101284200, COSV67064699; called by muse, mutect2, varscan2
- ST6GAL2 | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | PolyPhen probably damaging (0.967); catalogued as COSV62418387; called by muse, mutect2, varscan2
- STING1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100423452; called by muse, mutect2, varscan2
- TBX4 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.952); catalogued as rs1207189204, COSV99540033; called by muse, mutect2
- TPP2 | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs745493498, COSV101060284; called by muse, mutect2, varscan2
- TRMT10C | c.748A>C p.I250L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99998296; called by muse, mutect2
- TUBA3E | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV100471560; called by muse, mutect2, varscan2
- VAV3 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.15); catalogued as COSV64070278; called by muse, mutect2, varscan2
- ZFYVE9 | c.3370C>T p.Q1124* | Nonsense Mutation (SNP) | VAF 16/165 reads (10%) | catalogued as COSV99820090; called by muse, mutect2
- ZNF527 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as rs2385182; called by muse, mutect2, varscan2
- ZNF776 | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100414192; called by muse, mutect2
- PTH2R | c.1093del p.T365Hfs*6 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- ADAM12 | c.1656C>A p.V552= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs369236254; called by mutect2, varscan2
- ADRB3 | c.330C>T p.C110= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100799890; called by muse, mutect2, varscan2
- ASAH1 | c.969C>A p.L323= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV100025741; called by muse, mutect2, varscan2
- ATXN2L | c.3021G>A p.Q1007= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100293785; called by muse, mutect2, varscan2
- AUP1 | c.201G>A p.R67= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99239714; called by muse, mutect2, varscan2
- BAHCC1 | c.7059C>T p.G2353= | Silent (SNP) | VAF 6/172 reads (3%) | catalogued as COSV100311704; called by muse, mutect2
- CCDC73 | c.612A>G p.K204= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs756424576, COSV58802368; called by muse, mutect2, varscan2
- CTNND2 | c.3549C>T p.S1183= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1288565690, COSV58891556, COSV58899350; called by muse, mutect2, varscan2
- DCAF4L2 | c.363C>T p.Y121= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs752826822, COSV60480690; called by muse, mutect2
- DHRS4 | c.552C>A p.V184= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV100365899; called by muse, mutect2
- FOXN3 | c.339C>T p.C113= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as COSV99726563; called by muse, mutect2, varscan2
- GATA4 | c.906C>T p.H302= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs201516339; ClinVar: likely benign; called by muse, mutect2, varscan2
- GJA1 | c.291C>T p.F97= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99247022; called by muse, mutect2, varscan2
- GUCY2C | c.2478C>T p.Y826= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV99663702; called by muse, mutect2
- HMMR | c.231T>C p.S77= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100701004; called by muse, mutect2, varscan2
- LAMA1 | c.6219C>T p.D2073= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs751773541, COSV67531675; called by muse, mutect2, varscan2
- RBM45 | c.1365G>A p.V455= (on ENST00000616198 / NM_001365579.1; = p.V453= on NM_152945.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs1402183904, COSV99617735; called by muse, mutect2, varscan2
- RHD | c.285C>T p.D95= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as rs770315685, COSV59647026; called by muse, mutect2, varscan2
- SCRN1 | c.387C>T p.V129= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as rs1207364802, COSV99621345; called by muse, mutect2
- SPECC1 | c.3073T>C p.L1025= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV99822119; called by muse, mutect2
- WFDC1 | c.33C>T p.C11= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs771082930, COSV99550759; called by muse, mutect2, varscan2
- ZFP28 | c.2544G>A p.T848= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs928150808, COSV56735855; called by muse, mutect2
- ZNF677 | c.891C>G p.G297= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs1277586483, COSV100447970; called by muse, mutect2
- ZNRF4 | c.699C>T p.H233= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs200409035, COSV99706458; called by mutect2, varscan2
- ZSWIM4 | c.1086C>A p.L362= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99584961; called by muse, mutect2, varscan2
- CNKSR1 | c.-1C>G | 5'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100836743; called by muse, mutect2, varscan2
- WASF4P | n.1010C>T | RNA (SNP) | VAF 11/123 reads (9%) | catalogued as rs782813349; called by muse, mutect2, varscan2
